Somatic mutation profile of tumor specimen MP2PRT-PAUZKL-TMP1-A (aliquot MP2PRT-PAUZKL-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUZKL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,747 days).
Specimen MP2PRT-PAUZKL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f468abda-b241-463c-9ab6-49291562e280.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUZKL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUZKL-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9a6dcd4-61fe-43d2-9a75-b1b49e001b01

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GDF5 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 38/784 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs144074930; called by muse, mutect2
- H2BW2 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as rs782445611, COSV54582538; called by muse, mutect2
- HSPA4L | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141362649; called by muse, mutect2, varscan2
- PELI1 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 103/439 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs1215474532; called by muse, mutect2, varscan2
- ZDBF2 | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs760671336; called by muse, mutect2
- COBLL1 | c.3389T>C p.I1130T (on ENST00000392717; = p.I1092T on NM_014900.5) | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DUSP16 | c.1251A>C p.L417F | Missense Mutation (SNP) | VAF 129/484 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGR | c.2680A>T p.T894S | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLAC9 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 23/825 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC25A46 | c.257dup p.G87Rfs*9 | Frame Shift Ins (INS) | VAF 75/750 reads (10%) | called by mutect2, pindel
- ZNF235 | c.1872G>C p.E624D | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- OR10G8 | c.27G>A p.A9= | Silent (SNP) | VAF 27/474 reads (6%) | catalogued as rs182956274; called by muse, mutect2
- PUSL1 | c.567G>A p.P189= | Silent (SNP) | VAF 219/747 reads (29%) | catalogued as rs747533976; called by muse, mutect2, varscan2
- SORBS2 | c.2145G>A p.K715= | Silent (SNP) | VAF 92/463 reads (20%) | catalogued as rs758419578; called by muse, mutect2, varscan2
